Somatic mutation profile of tumor specimen TCGA-AB-2911-03A (aliquot TCGA-AB-2911-03A-01W-0732-08) from TCGA case TCGA-AB-2911, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.2 years (18,689 days).
Specimen TCGA-AB-2911-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 086f89f3-eab9-45a7-b1f9-5ff277bd0a6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2911-11A (Solid Tissue Normal), aliquot TCGA-AB-2911-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/016bbfe2-53fa-4def-9f1e-2bacdfeea18d

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- GRK2 | c.827-2A>G p.X276_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV57954213; called by muse, mutect2, varscan2
- SLC25A25 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.483); catalogued as rs765220171, COSV66087422; called by mutect2, varscan2
